Somatic mutation profile of tumor specimen TCGA-AA-3496-01A (aliquot TCGA-AA-3496-01A-21D-1835-10) from TCGA case TCGA-AA-3496, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 83.3 years (30,438 days).
Specimen TCGA-AA-3496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 832c4bd8-e018-4d10-844d-39045c39ffae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3496-11A (Solid Tissue Normal), aliquot TCGA-AA-3496-11A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7685c91e-b31b-44b3-b877-5c322943620c

The open-access MAF lists 109 somatic variants for this specimen: 80 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 25, Frame Shift Ins 7, Frame Shift Del 5, Nonsense Mutation 4, RNA 3, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.1510dup p.I504Nfs*7 | Frame Shift Ins (INS) | VAF 161/392 reads (41%) | catalogued as rs775735278; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 12/29 reads (41%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCF2 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55180869; called by muse, mutect2, varscan2
- ADGRL1 | c.3259G>A p.A1087T (on ENST00000340736 / NM_001008701.3; = p.A1082T on NM_014921.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.062); catalogued as rs576856623, COSV61563740; called by muse, mutect2, varscan2
- ADRA2B | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV101337348; called by muse, mutect2, varscan2
- ALOX15 | c.1056C>A p.F352L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as rs143365387; called by muse, mutect2, varscan2
- ANGPTL1 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs748411414, COSV52366862, COSV99328015; called by muse, mutect2, varscan2
- ANK2 | c.10235A>G p.E3412G | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100000355; called by muse, mutect2, varscan2
- ARHGAP31 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51795895; called by muse, mutect2, varscan2
- ATF2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs767222965, COSV51367838; called by muse, mutect2, varscan2
- ATR | c.4900G>A p.D1634N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100637834, COSV99052609; called by muse, mutect2, varscan2
- C19orf53 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.736); catalogued as COSV50003633; called by muse, varscan2
- CABIN1 | c.3529G>C p.E1177Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as COSV99572863; called by muse, mutect2, varscan2
- CEP85L | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs138089888; called by muse, mutect2, varscan2
- CGAS | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV64808071; called by muse, mutect2, varscan2
- CLCA1 | c.2174_2177del p.Q725Rfs*34 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs778844871; called by mutect2, pindel
- DNAH9 | c.5899G>A p.G1967S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs141526585, COSV99304798, COSV99306181; called by muse, mutect2, varscan2
- ECPAS | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52208483; called by muse, mutect2, varscan2
- ELFN2 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV101297494; called by muse, mutect2, varscan2
- EMC1 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761543184, COSV100617442; called by muse, mutect2, varscan2
- EPS8L1 | c.1678C>T p.P560S (on ENST00000201647 / NM_133180.3; = p.P433S on NM_017729.3) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52379918; called by muse, mutect2, varscan2
- ERICH3 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs747052542, COSV100443727; called by muse, mutect2, varscan2
- FILIP1 | c.1995G>T p.Q665H | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV99384140; called by muse, mutect2, varscan2
- FLG | c.6163G>C p.D2055H | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100911092; called by muse, mutect2, varscan2
- FLG | c.5801G>T p.W1934L | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1400244783, COSV64244718; called by muse, mutect2, varscan2
- GFRA2 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100151520; called by muse, mutect2, varscan2
- GRIK4 | c.2349G>A p.W783* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101483508; called by muse, mutect2, varscan2
- IQSEC3 | c.1908C>A p.N636K (on ENST00000538872 / NM_001170738.2; = p.N333K on NM_015232.1) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1311044537, COSV100406943; called by muse, mutect2, varscan2
- KCTD18 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100728838; called by muse, mutect2, varscan2
- KIR2DL3 | c.714C>T p.T238= | Splice Region (SNP) | VAF 31/106 reads (29%) | catalogued as rs781347297, COSV60895313; called by mutect2, varscan2
- KMT2C | c.9650G>A p.R3217H | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775712660, COSV51522849; called by muse, mutect2, varscan2
- KMT2C | c.4129A>T p.R1377* | Nonsense Mutation (SNP) | VAF 63/131 reads (48%) | catalogued as COSV100069001; called by muse, mutect2, varscan2
- KRBA1 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.571); catalogued as rs1164537742, COSV99752328; called by muse, mutect2
- LINGO1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs751063775, COSV100796320; called by muse, mutect2, varscan2
- MICALL1 | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270050907, COSV99317095; called by muse, mutect2, varscan2
- MYBBP1A | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs754670204, COSV54602374; called by muse, mutect2, varscan2
- MYO7B | c.5038G>A p.D1680N | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374902911, COSV67344167; called by muse, mutect2, varscan2
- NBEA | c.6227G>A p.R2076H | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172372804, COSV100077859; called by muse, mutect2, varscan2
- NEB | c.16715A>C p.K5572T | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50807925; called by muse, mutect2
- NID1 | c.1855G>A p.V619I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs148420954; called by muse, mutect2, varscan2
- OGFR | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99283842; called by muse, mutect2, varscan2
- PCDHA7 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs368032433, COSV65338759; called by muse, mutect2, varscan2
- PCDHB1 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs376341784; called by muse, mutect2, varscan2
- PCDHGA8 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53896288; called by mutect2, varscan2
- PGPEP1L | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs761032396, COSV100967265; called by muse, varscan2
- PLEKHA1 | c.107A>G p.E36G | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV100935455; called by muse, mutect2, varscan2
- PLEKHA5 | c.2774A>T p.N925I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100163729, COSV54707271; called by muse, mutect2, varscan2
- PNLIP | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs1237900414, COSV100981689, COSV65040987; called by muse, mutect2, varscan2
- PRB3 | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs767951787, COSV54387956; called by muse, mutect2, varscan2
- PRX | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1347911633, COSV99397563; called by muse, mutect2, varscan2
- PXDNL | c.3206C>G p.A1069G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV62477564; called by muse, mutect2, varscan2
- RAD51C | c.314del p.S105* | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | catalogued as COSV53627107; called by mutect2, pindel, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 18/153 reads (12%) | catalogued as rs756557178; called by mutect2, varscan2
- RBM28 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs369500252; called by muse, mutect2, varscan2
- ROS1 | c.5941A>T p.T1981S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100876653; called by muse, mutect2, varscan2
- RP1L1 | c.2983G>A p.G995R | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as COSV101223044; called by muse, mutect2, varscan2
- RPUSD1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as rs752397101, COSV50100235, COSV50103164; called by muse, mutect2, varscan2
- SLC6A1 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1479789276, COSV99822542; called by muse, mutect2, varscan2
- SLC7A4 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as rs148390805; called by muse, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | catalogued as rs750890082; called by mutect2, varscan2
- ST8SIA4 | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | PolyPhen probably damaging (0.964); catalogued as COSV99185150; called by muse, mutect2, varscan2
- SV2B | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100370483; called by muse, mutect2, varscan2
- TSPEAR | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs868982192, COSV59967383; called by muse, mutect2, varscan2
- TTN | c.83234G>A p.S27745N (on ENST00000591111; = p.S20321N on NM_003319.4) | Missense Mutation (SNP) | VAF 69/96 reads (72%) | PolyPhen benign (0.013); catalogued as COSV100600351; called by muse, mutect2, varscan2
- TUBGCP2 | c.2551G>A p.G851S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs775048794, COSV53302950; called by muse, mutect2, varscan2
- VIRMA | c.4919G>A p.R1640H | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52589461; called by muse, mutect2, varscan2
- VTN | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs781937745, COSV99412034; called by muse, mutect2, varscan2
- XAGE5 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0.124); catalogued as rs782286603, COSV100657801; called by muse, mutect2, varscan2
- ZDHHC20 | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100203355; called by muse, mutect2, varscan2
- ZNF235 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.538); catalogued as COSV99349301; called by muse, mutect2, varscan2
- ZNF423 | c.2243C>T p.A748V (on ENST00000563137 / NM_001379286.1; = p.A740V on NM_015069.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs923711687, COSV52176934; called by muse, varscan2
- ZNF93 | c.1098G>T p.K366N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100652201; called by muse, mutect2, varscan2
- ASTN1 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NDUFAF2 | c.185_186del p.Y62* | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- OR10A4 | c.324dup p.G109Wfs*4 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- SLC17A6 | c.375dup p.M126Dfs*66 | Frame Shift Ins (INS) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- SPAG9 | c.1450dup p.R484Kfs*7 (on ENST00000262013 / NM_001130528.3; = p.R470Kfs*7 on NM_003971.6) | Frame Shift Ins (INS) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2041C>T p.R681W (on ENST00000621492; = p.R647W on NM_025248.3) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- TP53 | c.686_687del p.C229Yfs*10 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- WFIKKN2 | c.425_426dup p.S143Pfs*32 | Frame Shift Ins (INS) | VAF 22/46 reads (48%) | called by mutect2, pindel, varscan2
- ABCA3 | c.306G>A p.V102= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100068168; called by muse, mutect2, varscan2
- AFF3 | c.693G>A p.P231= | Silent (SNP) | VAF 50/59 reads (85%) | catalogued as rs774845734, COSV100418217; called by muse, varscan2
- ARHGAP31 | c.1155C>T p.T385= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1426931415, COSV51800255; called by muse, mutect2, varscan2
- CABIN1 | c.2734C>T p.L912= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs1387107992, COSV99572861; called by muse, varscan2
- CD1A | c.96C>A p.I32= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56864777, COSV99192241; called by mutect2, varscan2
- F5 | c.417C>T p.D139= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs749722664, COSV63120009; ClinVar: likely benign; called by muse, mutect2, varscan2
- FTCD | c.1521C>T p.D507= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs141582814; called by muse, mutect2, varscan2
- GCNT1 | c.867C>T p.F289= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs1467025804, COSV65056836; called by muse, mutect2, varscan2
- GPLD1 | c.192C>T p.I64= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs373845669; called by muse, mutect2, varscan2
- GPR153 | c.1008G>A p.P336= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs143877668; called by muse, mutect2, varscan2
- IRX1 | c.765C>T p.P255= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100116323; called by muse, mutect2, varscan2
- ITPR1 | c.2095C>T p.L699= (on ENST00000354582; = p.L684= on NM_002222.7) | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100230200; called by muse, mutect2, varscan2
- KCNA4 | c.486C>T p.G162= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1357760740, COSV60252979; called by muse, mutect2, varscan2
- KCNH4 | c.717C>T p.Y239= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs574588024, COSV99236909; called by mutect2, varscan2
- KLHDC8A | c.369G>A p.T123= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV65679143; called by muse, mutect2, varscan2
- LHFPL4 | c.126C>T p.I42= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99805174; called by muse, mutect2, varscan2
- MCC | c.534G>A p.K178= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as COSV100202221; called by muse, mutect2, varscan2
- MVK | c.927C>T p.G309= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs762580578, COSV99949900; ClinVar: likely benign; called by muse, mutect2, varscan2
- MXRA5 | c.8061C>T p.R2687= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as rs750393124, COSV54230638; called by muse, mutect2, varscan2
- NBEA | c.4417A>C p.R1473= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100077857; called by muse, mutect2, varscan2
- PLEKHM2 | c.2433C>T p.T811= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs772926237, COSV101009064; called by mutect2, varscan2
- PXDNL | c.2958C>T p.S986= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs952661664, COSV62477568; called by muse, mutect2, varscan2
- SCN5A | c.2211G>A p.E737= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs967241166, COSV100347045; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLAMF1 | c.390C>T p.R130= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV99349059; called by muse, mutect2, varscan2
- SYNE1 | c.8169C>T p.H2723= (on ENST00000367255 / NM_182961.4; = p.H2730= on NM_033071.3) | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs371449580; called by muse, mutect2, varscan2
- CCDC144NL | n.573C>T | RNA (SNP) | VAF 16/29 reads (55%) | catalogued as rs759231648, COSV100018898; called by muse, mutect2, varscan2
- MAGEA5 | n.273A>C | RNA (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2
- SSPOP | n.1409G>A | RNA (SNP) | VAF 7/9 reads (78%) | catalogued as rs761863381, COSV50489322; called by muse, varscan2
- ZSCAN21 | c.*279A>G | 3'UTR (SNP) | VAF 28/56 reads (50%) | catalogued as COSV99460732; called by mutect2, varscan2
